CCDI case PBBMMW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/453452a9-3bc0-4fb0-bb6c-31e7001bc756

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 6.3 years (2,309 days).

Biospecimens (3 samples)
- Sample 0DCMP4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCMP5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCMP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
